Somatic mutation profile of tumor specimen 0DWESC from CCDI case PBCPCW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.4 years (1,956 days).
Specimen 0DWESC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70c79e20-f7b7-406b-beb9-3d925553f326.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWES3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab73ab62-30c7-42c1-b39b-df54884fb092

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Nonsense Mutation 3, Missense Mutation 2, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.3916C>T p.R1306* | Nonsense Mutation (SNP) | VAF 77/337 reads (23%) | catalogued as rs376576925, CM981381, COSV62193951; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GAB4 | c.153dup p.E52Rfs*22 | Frame Shift Ins (INS) | VAF 74/380 reads (19%) | catalogued as rs764879401; called by pindel, varscan2
- NF1 | c.4234A>T p.R1412* (on ENST00000358273 / NM_001042492.3; = p.R1391* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 96/355 reads (27%) | catalogued as CM1211610; called by muse, mutect2, varscan2
- IGBP1 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 142/536 reads (26%) | called by muse, mutect2, varscan2
- L1CAM | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 23/275 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYP | c.251C>A p.A84E | Missense Mutation (SNP) | VAF 28/317 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2
- GATA1 | c.351T>C p.P117= | Silent (SNP) | VAF 16/388 reads (4%) | called by muse, mutect2
